Somatic mutation profile of tumor specimen 1105191 (aliquot 7316UP-483-1105191) from CPTAC case C223491, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS.
Specimen 1105191: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 227e4f5a-2d91-4911-9a79-b7aed2f9bf46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105289 (Blood Derived Normal), aliquot 7316UP-483-1105289; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04a8cd15-7706-4a45-abbc-10faaea063a9

The open-access MAF lists 1,205 somatic variants for this specimen: 821 protein-altering or splice-affecting, 227 silent, 157 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 534, Silent 227, Frame Shift Del 191, Intron 81, 3'UTR 31, Nonsense Mutation 30, Frame Shift Ins 29, Splice Site 16, RNA 15, 5'UTR 13, 5'Flank 11, In Frame Del 10.

Variants (750 of 1,205; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 72/178 reads (40%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, varscan2
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 62/174 reads (36%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- KAT6A | c.4645G>A p.G1549S | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064794000, COSV55907802; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 80/186 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MYO7A | c.6487G>A p.G2163S | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs747656448, CM990906, COSV60020751; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 24/59 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTCH1 | c.114dup p.L39Afs*51 | Frame Shift Ins (INS) | VAF 67/186 reads (36%) | catalogued as rs751977093; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 84/251 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 58/161 reads (36%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RHOA | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 37/99 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV69041545, COSV69041670; called by muse, mutect2, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA5 | c.426del p.P143Lfs*3 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as COSV67018434; called by mutect2, pindel, varscan2
- ABCC9 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV53965219; called by muse, mutect2, varscan2
- ACADL | c.272A>G p.E91G | Missense Mutation (SNP) | VAF 79/283 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs1319500123, COSV52055319; called by muse, mutect2, varscan2
- ADAM22 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 75/157 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55970780, COSV99718649; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4595G>A p.R1532H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs747642979, COSV65878254; called by muse, mutect2, varscan2
- ADIPOR1 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs369139073; called by muse, mutect2, varscan2
- AGAP1 | c.1727G>A p.R576Q (on ENST00000304032 / NM_001037131.3; = p.R523Q on NM_014914.5) | Missense Mutation (SNP) | VAF 69/202 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs971441146; called by muse, mutect2, varscan2
- AHCTF1 | c.2911-1G>T p.X971_splice (on ENST00000366508; = p.X945_splice on NM_015446.5) | Splice Site (SNP) | VAF 35/118 reads (30%) | catalogued as COSV100404178; called by muse, mutect2, varscan2
- AHCYL2 | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs766038729, COSV61491254; called by muse, mutect2, varscan2
- AHNAK | c.2282G>T p.G761V | Missense Mutation (SNP) | VAF 125/305 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs754327408; called by muse, mutect2, varscan2
- AKAP12 | c.3479del p.P1160Lfs*18 | Frame Shift Del (DEL) | VAF 65/196 reads (33%) | catalogued as COSV53580835; called by mutect2, pindel, varscan2
- ALCAM | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV60253542; called by muse, mutect2, varscan2
- ANAPC11 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752711149; called by muse, mutect2, varscan2
- ANO8 | c.1087del p.L363Cfs*24 | Frame Shift Del (DEL) | VAF 19/35 reads (54%) | catalogued as COSV50178856; called by mutect2, pindel, varscan2
- ANO8 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as COSV99344161; called by muse, mutect2, varscan2
- AOAH | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV99333441; called by muse, mutect2, varscan2
- AP2A2 | c.170del p.K57Sfs*24 | Frame Shift Del (DEL) | VAF 22/42 reads (52%) | catalogued as rs753029866; called by mutect2, varscan2
- APC | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767741687, COSV57361006; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP28 | c.904del p.R302Efs*16 (on ENST00000383472 / NM_001366230.1; = p.R143Efs*16 on NM_001010000.3) | Frame Shift Del (DEL) | VAF 40/116 reads (34%) | catalogued as COSV51632340; called by mutect2, pindel, varscan2
- ARHGAP33 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1363584324, COSV99140221; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 55/137 reads (40%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARSI | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.154); catalogued as rs763136370, COSV60817209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASCL4 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.11); catalogued as rs746756373, COSV100661143; called by muse, mutect2, varscan2
- ATP10D | c.1848del p.L617Cfs*41 | Frame Shift Del (DEL) | VAF 13/23 reads (57%) | catalogued as rs764067652, COSV56705401; called by mutect2, pindel, varscan2
- ATR | c.5440del p.R1814Efs*10 | Frame Shift Del (DEL) | VAF 27/100 reads (27%) | catalogued as rs1268253442; called by mutect2, pindel, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs1288664341; called by mutect2, pindel, varscan2
- AXDND1 | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV62640575; called by muse, mutect2, varscan2
- AZU1 | c.483del p.R162Vfs*11 | Frame Shift Del (DEL) | VAF 39/131 reads (30%) | catalogued as rs772652509, COSV99297150; called by mutect2, pindel, varscan2
- BAIAP3 | c.1928C>T p.A643V | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs199973519, COSV99136344; called by muse, mutect2, varscan2
- BCHE | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.178); catalogued as rs1230054763, COSV52256733; called by muse, mutect2, varscan2
- BCL6B | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs578215266, COSV53426078, COSV53427535; called by muse, mutect2, varscan2
- BNC2 | c.159_162del p.E55Hfs*13 | Frame Shift Del (DEL) | VAF 132/367 reads (36%) | catalogued as rs1391476398; called by mutect2, pindel, varscan2
- BOC | c.2420G>A p.C807Y | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56347703, COSV56359507; called by muse, mutect2, varscan2
- BRD4 | c.2336del p.P779Rfs*15 | Frame Shift Del (DEL) | VAF 26/104 reads (25%) | catalogued as COSV54583043; called by mutect2, pindel
- C14orf39 | c.1762del p.*588Efs*16 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | catalogued as rs780875081; called by mutect2, varscan2
- C2CD2L | c.1892G>A p.R631H | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs561253373; called by muse, mutect2, varscan2
- C3 | c.299A>G p.K100R | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV55575801; called by muse, mutect2, varscan2
- CACNA1A | c.2545G>A p.V849M | Missense Mutation (SNP) | VAF 165/440 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1168020406, COSV64202185; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1B | c.4739G>A p.R1580H | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377465019; called by muse, mutect2, varscan2
- CASP8AP2 | c.3842C>T p.A1281V | Missense Mutation (SNP) | VAF 55/97 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1217133573; called by muse, mutect2, varscan2
- CCDC105 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.15); catalogued as rs760693691, COSV52963515; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 30/75 reads (40%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC85C | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1267017946; called by muse, mutect2
- CCDC86 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs573397831; called by muse, mutect2, varscan2
- CCNJL | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 121/166 reads (73%) | SIFT tolerated (0.29); PolyPhen benign (0.096); catalogued as rs747122783; called by muse, mutect2, varscan2
- CCT6B | c.725+1G>A p.X242_splice | Splice Site (SNP) | VAF 13/42 reads (31%) | catalogued as rs376851436, COSV58489082; called by muse, mutect2, varscan2
- CD207 | c.743del p.G248Dfs*8 | Frame Shift Del (DEL) | VAF 13/107 reads (12%) | catalogued as rs782658356; called by mutect2, pindel, varscan2
- CDC42BPG | c.4293del p.F1431Lfs*16 | Frame Shift Del (DEL) | VAF 76/206 reads (37%) | catalogued as rs570535506; called by mutect2, pindel, varscan2
- CDCA7 | c.910C>T p.R304C (on ENST00000347703 / NM_145810.3; = p.R383C on NM_031942.5) | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60720386; called by muse, mutect2, varscan2
- CDH23 | c.1823G>A p.S608N | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs774745111; called by muse, mutect2, varscan2
- CDHR5 | c.2365G>A p.E789K (on ENST00000358353 / NM_001171968.2; = p.E795K on NM_021924.5) | Missense Mutation (SNP) | VAF 103/287 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as rs371913447; called by muse, mutect2, varscan2
- CEACAM16 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs771309051; called by muse, mutect2, varscan2
- CELSR3 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs1031937400; called by muse, mutect2, varscan2
- CFAP44 | c.2218C>T p.P740S | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs368620724; called by muse, mutect2, varscan2
- CHD4 | c.3446G>A p.R1149Q (on ENST00000357008 / NM_001363606.2; = p.R1162Q on NM_001273.5) | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58903721; called by muse, mutect2, varscan2
- CHRNA5 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs200127699, COSV55138194, COSV55139165; called by muse, mutect2, varscan2
- CKAP2 | c.283G>A p.V95M (on ENST00000378037 / NM_001098525.2; = p.V94M on NM_018204.5) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1566098525; called by muse, mutect2, varscan2
- CKLF | c.447del p.E150Kfs*? (on ENST00000264001 / NM_016951.4; = p.E65Kfs*? on NM_016326.3) | Frame Shift Del (DEL) | VAF 52/144 reads (36%) | catalogued as rs754415052; called by mutect2, varscan2
- CLEC16A | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs367927027; called by muse, mutect2, varscan2
- CLSPN | c.1757G>A p.S586N | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1557515939; called by muse, mutect2, varscan2
- CNGA4 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 21/45 reads (47%) | catalogued as rs532111437, COSV66005224; called by muse, mutect2, varscan2
- COL20A1 | c.2582del p.G861Afs*23 | Frame Shift Del (DEL) | VAF 33/105 reads (31%) | catalogued as COSV100490176; called by mutect2, pindel, varscan2
- COL24A1 | c.3807del p.G1270Efs*68 | Frame Shift Del (DEL) | VAF 48/158 reads (30%) | catalogued as rs751232308; called by mutect2, pindel, varscan2
- COL27A1 | c.5059G>A p.A1687T | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs755869669, COSV61930209; called by muse, mutect2, varscan2
- CPNE5 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as rs1218572824, COSV55196220; called by muse, varscan2
- CPNE5 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372874067; called by muse, varscan2
- CPSF7 | c.1295G>A p.R432Q (on ENST00000394888 / NM_001136040.4; = p.R475Q on NM_024811.4) | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs775930483, COSV100467717; called by muse, mutect2, varscan2
- CPT1A | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 139/343 reads (41%) | catalogued as rs767241290; called by muse, mutect2, varscan2
- CSMD1 | c.7009G>T p.G2337W (on ENST00000520002; = p.G2336W on NM_033225.6) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866721621; called by muse, mutect2, varscan2
- CTIF | c.570_572del p.R191del | In Frame Del (DEL) | VAF 39/107 reads (36%) | catalogued as rs1195439301; called by pindel, varscan2
- CTNNA3 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 118/309 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs139378888; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNB1 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 188/464 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as rs764576683, COSV62692581; called by muse, mutect2, varscan2
- CWC27 | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs763896931, COSV66887071; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 13/102 reads (13%) | catalogued as rs756254049; called by mutect2, pindel
- DAPL1 | c.127del p.T43Qfs*21 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | catalogued as rs763165810; called by mutect2, pindel, varscan2
- DCLK3 | c.1037G>A p.G346D | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs1240940774; called by muse, mutect2, varscan2
- DDX3X | c.1421G>A p.R474H (on ENST00000399959; = p.R475H on NM_001356.5) | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV67863186; called by muse, mutect2, varscan2
- DDX5 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs782748084; called by muse, mutect2, varscan2
- DENND2C | c.387_389del p.E129del | In Frame Del (DEL) | VAF 33/136 reads (24%) | catalogued as rs774959242; called by pindel, varscan2
- DGKA | c.2176del p.R726Afs*9 | Frame Shift Del (DEL) | VAF 49/131 reads (37%) | catalogued as COSV59384233; called by mutect2, pindel, varscan2
- DGLUCY | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs759389819; called by muse, mutect2, varscan2
- DHPS | c.758C>A p.P253Q | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV99269620; called by muse, mutect2, varscan2
- DLC1 | c.2057C>T p.A686V (on ENST00000276297 / NM_001348081.2; = p.A249V on NM_006094.5) | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs142931995; called by muse, mutect2, varscan2
- DLG3 | c.1633C>T p.Q545* (on ENST00000374360 / NM_021120.4; = p.Q208* on NM_020730.3) | Nonsense Mutation (SNP) | VAF 53/165 reads (32%) | catalogued as COSV52085052; called by muse, mutect2, varscan2
- DMWD | c.1406C>T p.T469M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.613); catalogued as rs779740321; called by mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAH2 | c.11786T>C p.I3929T | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs777514853; called by muse, mutect2, varscan2
- DNAH6 | c.911del p.N304Ifs*16 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | catalogued as rs763637561; called by mutect2, pindel, varscan2
- DOK1 | c.245dup p.E83* | Frame Shift Ins (INS) | VAF 92/252 reads (37%) | catalogued as rs750803751; called by mutect2, varscan2
- DSCAML1 | c.5048G>A p.R1683Q (on ENST00000321322; = p.R1623Q on NM_020693.4) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs756425038; called by muse, mutect2, varscan2
- DUS2 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768614400; called by muse, mutect2, varscan2
- DZIP1L | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs762332715; called by muse, mutect2, varscan2
- ELFN1 | c.1819G>A p.A607T | Missense Mutation (SNP) | VAF 93/201 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs777903379, COSV70036773; called by muse, mutect2, varscan2
- EPC1 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 39/129 reads (30%) | catalogued as COSV53925685; called by muse, mutect2, varscan2
- EPHA2 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 110/259 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as COSV100626213; called by muse, mutect2, varscan2
- EPHA8 | c.2287G>A p.A763T | Missense Mutation (SNP) | VAF 127/304 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs149930866; called by muse, mutect2, varscan2
- ERI2 | c.1766G>A p.S589N | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as rs775766126; called by muse, mutect2, varscan2
- ERICH3 | c.3506del p.N1169Tfs*2 | Frame Shift Del (DEL) | VAF 27/95 reads (28%) | catalogued as COSV58619446; called by mutect2, pindel, varscan2
- ERMAP | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs563298024, COSV60273887; called by muse, mutect2, varscan2
- ESPNL | c.2264C>T p.T755M | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs1000805144, COSV58036366; called by muse, mutect2, varscan2
- EXOC3 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1402255797; called by muse, mutect2, varscan2
- FADS3 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.477); catalogued as rs377115399, COSV53877446; called by muse, mutect2, varscan2
- FAM234B | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs148007869; called by muse, mutect2, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 71/88 reads (81%) | catalogued as rs748967872; called by mutect2, varscan2
- FARP2 | c.2743C>T p.R915W | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1449861556; called by muse, mutect2, varscan2
- FAT3 | c.4902G>A p.M1634I | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV99963809; called by muse, mutect2, varscan2
- FCGBP | c.1453G>A p.G485S | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs1475266054; called by muse, mutect2, varscan2
- FGD3 | c.367del p.Q123Rfs*51 | Frame Shift Del (DEL) | VAF 28/96 reads (29%) | catalogued as rs777351004, COSV100490512; called by mutect2, pindel, varscan2
- FGF8 | c.628G>A p.E210K (on ENST00000344255 / NM_033164.4; = p.E192K on NM_006119.6) | Missense Mutation (SNP) | VAF 91/228 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as rs1370886145; called by muse, mutect2, varscan2
- FGFR2 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 83/247 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs781714766, COSV60641778; called by muse, mutect2, varscan2
- FKRP | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs754088436; called by muse, mutect2, varscan2
- FLT3LG | c.351del p.S118Afs*24 | Frame Shift Del (DEL) | VAF 28/34 reads (82%) | catalogued as rs769482947; called by mutect2, varscan2
- FMNL3 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as rs754025129; called by muse, mutect2, varscan2
- FOXD4L1 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 110/462 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs768136068; called by muse, mutect2, varscan2
- FREM2 | c.6958G>A p.V2320M | Missense Mutation (SNP) | VAF 102/230 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs1268483221, COSV54833272; called by muse, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 33/99 reads (33%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FRZB | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1442023364; called by muse, mutect2, varscan2
- FZD2 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 97/237 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs770035472, COSV59528209, COSV59528679; called by muse, mutect2, varscan2
- GABRB1 | c.78C>T p.H26= | Splice Region (SNP) | VAF 45/116 reads (39%) | catalogued as COSV99783620; called by muse, mutect2, varscan2
- GARRE1 | c.3184C>T p.R1062C | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as rs530232322; called by muse, mutect2, varscan2
- GBE1 | c.1079C>T p.T360M | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs745405800; called by muse, mutect2, varscan2
- GDA | c.579-1G>T p.X193_splice | Splice Site (SNP) | VAF 22/55 reads (40%) | catalogued as COSV52998111; called by muse, mutect2, varscan2
- GFPT2 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 87/206 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs757899837, COSV53806552; called by muse, mutect2, varscan2
- GLA | c.1166C>A p.P389H | Missense Mutation (SNP) | VAF 102/241 reads (42%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.996); catalogued as CM078393, CM138906; called by muse, mutect2, varscan2
- GLDC | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 94/241 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761957837, CM1510120, COSV58678266; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPATCH8 | c.2158A>G p.K720E | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.473); catalogued as rs751562055; called by muse, mutect2
- GPHN | c.949C>T p.R317C (on ENST00000315266 / NM_001377519.1; = p.R350C on NM_020806.5) | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59488842; called by muse, mutect2, varscan2
- GPR142 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as rs367783578; called by muse, mutect2, varscan2
- GPR143 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 107/296 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.416); catalogued as COSV101102214; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 72/245 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.63); catalogued as rs200522526, COSV100441347; called by muse, mutect2, varscan2
- HMCN2 | c.12524C>T p.T4175M | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.51); catalogued as rs960747751; called by muse, mutect2, varscan2
- HMGCS1 | c.1438G>A p.G480R | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs1397860513; called by muse, mutect2, varscan2
- HMGXB3 | c.3887G>A p.R1296Q (on ENST00000613459; = p.R1050Q on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745836949; called by muse, mutect2, varscan2
- HOXA11 | c.895del p.I299Lfs*30 | Frame Shift Del (DEL) | VAF 108/266 reads (41%) | catalogued as rs777829525; called by mutect2, varscan2
- HRG | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs370234178; called by muse, mutect2, varscan2
- HTATSF1 | c.1368del p.E457Rfs*35 | Frame Shift Del (DEL) | VAF 34/135 reads (25%) | catalogued as COSV54481935; called by mutect2, pindel, varscan2
- ICE1 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201580742; called by muse, mutect2, varscan2
- IGF1R | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 127/319 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs757536805; called by muse, mutect2, varscan2
- IGFBP5 | c.120dup p.S41Qfs*78 | Frame Shift Ins (INS) | VAF 20/50 reads (40%) | catalogued as rs748087175; called by mutect2, varscan2
- IGLON5 | c.750G>A p.W250* | Nonsense Mutation (SNP) | VAF 36/98 reads (37%) | catalogued as rs1423065925; called by muse, mutect2, varscan2
- IGSF22 | c.2306C>T p.T769I (on ENST00000319338; = p.T870I on NM_173588.4) | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs372092174; called by muse, mutect2, varscan2
- IGSF9B | c.2837G>A p.R946Q | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs756219238, COSV100316869; called by muse, mutect2, varscan2
- IL17REL | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.084); catalogued as rs866785241; called by muse, mutect2, varscan2
- ILVBL | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs370758360; called by muse, mutect2, varscan2
- IPO8 | c.167-1G>A p.X56_splice | Splice Site (SNP) | VAF 21/55 reads (38%) | catalogued as COSV99805501; called by muse, mutect2, varscan2
- IPO9 | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs1391897187, COSV64233730; called by muse, varscan2
- ITPR2 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1159482369, COSV67270866; called by muse, mutect2, varscan2
- ITPRIPL2 | c.861del p.T288Pfs*62 | Frame Shift Del (DEL) | VAF 59/152 reads (39%) | catalogued as rs761512894; called by mutect2, pindel, varscan2
- JAK3 | c.2084G>A p.C695Y | Missense Mutation (SNP) | VAF 75/158 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1203686982, COSV104438104; called by muse, mutect2, varscan2
- KANK1 | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 75/171 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.242); catalogued as rs146416309; called by muse, mutect2, varscan2
- KDM4D | c.278del p.K93Rfs*4 | Frame Shift Del (DEL) | VAF 34/85 reads (40%) | catalogued as rs142280183; called by mutect2, varscan2
- KIAA0825 | c.3032C>T p.A1011V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.096); catalogued as rs1351833883; called by muse, mutect2, varscan2
- KIAA1109 | c.6283C>T p.R2095C | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs528587230, COSV52667344; called by muse, mutect2, varscan2
- KIF26B | c.5116G>A p.A1706T | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs1454001800; called by muse, mutect2, varscan2
- KLHL10 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1302156953, COSV53173028; called by muse, mutect2, varscan2
- KLHL35 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.321); catalogued as COSV100888776; called by muse, mutect2, varscan2
- KLK6 | c.718dup p.T240Nfs*45 | Frame Shift Ins (INS) | VAF 44/137 reads (32%) | catalogued as rs750767249; called by mutect2, pindel, varscan2
- KNSTRN | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV51109762; called by muse, mutect2, varscan2
- KRT6B | c.395del p.P132Lfs*14 | Frame Shift Del (DEL) | VAF 134/766 reads (17%) | catalogued as rs772129177; called by mutect2, pindel, varscan2
- KRT80 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 75/206 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs564779835; called by muse, mutect2, varscan2
- L3MBTL3 | c.230del p.P77Rfs*32 | Frame Shift Del (DEL) | VAF 32/103 reads (31%) | catalogued as COSV62384647; called by mutect2, pindel, varscan2
- LARP4 | c.1843C>T p.R615* | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | catalogued as COSV53324578; called by muse, mutect2, varscan2
- LATS2 | c.1888G>T p.E630* | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as COSV101231712; called by muse, mutect2, varscan2
- LCAT | c.1289del p.P430Rfs*19 | Frame Shift Del (DEL) | VAF 25/78 reads (32%) | catalogued as CM125152; called by mutect2, pindel, varscan2
- LETM2 | c.1193C>T p.P398L (on ENST00000379957 / NM_001286819.2; = p.P303L on NM_144652.3) | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs1313584716; called by muse, mutect2, varscan2
- LMOD1 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 92/294 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs763440069, COSV66172684; called by muse, mutect2, varscan2
- LRIF1 | c.2099A>G p.H700R | Missense Mutation (SNP) | VAF 82/183 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs778203277; called by muse, mutect2, varscan2
- LRIG2 | c.2855A>C p.Q952P | Missense Mutation (SNP) | VAF 88/207 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1210989908; called by muse, mutect2, varscan2
- LRP1B | c.12349C>T p.H4117Y | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs759455625; called by muse, mutect2, varscan2
- LRRIQ1 | c.4624del p.I1542Ffs*17 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | catalogued as rs745692987; called by mutect2, varscan2
- LSG1 | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs763071707, COSV54569510; called by muse, mutect2, varscan2
- LTB4R2 | c.1150G>A p.G384S (on ENST00000528054; = p.G353S on NM_019839.5) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs756992579, COSV51864542; called by muse, mutect2
- LTK | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.358); catalogued as rs140090710; called by muse, mutect2, varscan2
- MACF1 | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | catalogued as COSV100482025; called by muse, mutect2, varscan2
- MAGEC1 | c.2240G>C p.C747S | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.227); catalogued as rs139916073; called by muse, mutect2, varscan2
- MAP3K21 | c.1674G>A p.Q558= | Splice Region (SNP) | VAF 34/114 reads (30%) | catalogued as rs547287571; called by muse, mutect2, varscan2
- MAPK7 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 79/173 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1212748750; called by muse, mutect2, varscan2
- MARF1 | c.4333C>A p.H1445N | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as rs777933126; called by muse, mutect2, varscan2
- MARK4 | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780763668, COSV53464983, COSV99489105; called by muse, mutect2, varscan2
- MAST2 | c.4904C>T p.S1635L | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs369652939; called by muse, mutect2, varscan2
- MBD1 | c.1241G>A p.R414Q (on ENST00000269468 / NM_001323950.1; = p.R358Q on NM_002384.2) | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs779064515; called by muse, mutect2
- MBD6 | c.1984del p.L662Yfs*13 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | catalogued as rs1163818902; called by mutect2, pindel, varscan2
- MED12 | c.3955C>T p.R1319C | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs901783069; called by muse, mutect2
- MED14 | c.3631C>A p.L1211I | Missense Mutation (SNP) | VAF 79/177 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61357419; called by muse, mutect2, varscan2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 60/138 reads (43%) | catalogued as rs745891632; called by mutect2, varscan2
- MIOS | c.1202G>T p.R401M | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV100402897; called by muse, mutect2, varscan2
- MMRN1 | c.3647del p.P1216Lfs*17 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | catalogued as COSV53334580, COSV53343010; called by mutect2, pindel, varscan2
- MOCOS | c.1898G>A p.R633Q | Missense Mutation (SNP) | VAF 130/300 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs766703333, COSV54345558; called by muse, mutect2, varscan2
- MPP6 | c.917del p.K306Rfs*4 | Frame Shift Del (DEL) | VAF 24/56 reads (43%) | catalogued as rs757450051; ClinVar: not provided; called by mutect2, varscan2
- MRGPRG | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs1286401856; called by muse, mutect2, varscan2
- MRS2 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as rs776046884, COSV51234857, COSV99218637; called by muse, mutect2, varscan2
- MTMR12 | c.1853G>A p.S618N | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs762460927; called by muse, mutect2, varscan2
- MUC12 | c.14993G>A p.S4998N (on ENST00000379442; = p.S4855N on NM_001164462.1) | Missense Mutation (SNP) | VAF 86/227 reads (38%) | SIFT deleterious (0); catalogued as rs1267145306; called by muse, mutect2, varscan2
- MUC16 | c.31412del p.R10471Kfs*9 | Frame Shift Del (DEL) | VAF 21/46 reads (46%) | catalogued as rs1243024568, COSV67492204; called by mutect2, pindel, varscan2
- MUC19 | c.461del p.K154Sfs*87 | Frame Shift Del (DEL) | VAF 26/61 reads (43%) | catalogued as rs537060918; called by mutect2, varscan2
- MUC4 | c.11921G>A p.R3974H | Missense Mutation (SNP) | VAF 153/194 reads (79%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.448); catalogued as COSV57767737; called by muse, mutect2, varscan2
- MVD | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 82/230 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1281597517; called by muse, mutect2, varscan2
- MYO5A | c.3311A>G p.H1104R | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV62557643; called by muse, mutect2
- MYOC | c.425A>G p.Y142C | Missense Mutation (SNP) | VAF 108/361 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs576184926; called by muse, mutect2, varscan2
- MYOM2 | c.1827C>A p.T609= | Splice Region (SNP) | VAF 26/56 reads (46%) | catalogued as COSV100039002; called by muse, varscan2
- NACC2 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs746624435; called by muse, mutect2, varscan2
- NAPG | c.666-1G>A p.X222_splice | Splice Site (SNP) | VAF 30/56 reads (54%) | catalogued as rs1186333569, COSV59797326; called by muse, mutect2, varscan2
- NBEAL2 | c.6517G>A p.V2173M | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs768276685, COSV99438120; called by muse, mutect2, varscan2
- NDE1 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as rs749543506; called by muse, mutect2, varscan2
- NFRKB | c.2681C>T p.T894M (on ENST00000446488 / NM_001143835.2; = p.T919M on NM_006165.3) | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.113); catalogued as rs746347631; called by muse, mutect2, varscan2
- NLRC5 | c.3802C>T p.P1268S | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV52652338; called by muse, mutect2
- NLRP6 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763915009; called by muse, mutect2, varscan2
- NOL8 | c.1033G>A p.V345I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs750294867; called by muse, mutect2, varscan2
- NOTCH4 | c.5672dup p.G1892Rfs*24 | Frame Shift Ins (INS) | VAF 44/104 reads (42%) | catalogued as rs777647776; called by mutect2, varscan2
- NUAK2 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs532473739; called by muse, mutect2, varscan2
- NUDT1 | c.298G>A p.E100K (on ENST00000397048 / NM_198952.1; = p.E77K on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 130/332 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.183); catalogued as rs374195109; called by muse, mutect2, varscan2
- NUP188 | c.3460C>T p.R1154C | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs200827758; called by muse, mutect2, varscan2
- OBSCN | c.18265G>A p.A6089T | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs574502307; called by muse, mutect2, varscan2
- OBSCN | c.20977del p.A6993Pfs*79 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs762005098; called by mutect2, pindel, varscan2
- OR2M4 | c.174del p.M59Cfs*23 | Frame Shift Del (DEL) | VAF 30/98 reads (31%) | catalogued as COSV60708101; called by mutect2, pindel, varscan2
- OR2W3 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs201306772, COSV64457516; called by muse, mutect2
- OR3A1 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 71/160 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372689671; called by muse, mutect2, varscan2
- OR4C6 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.378); catalogued as rs763521348, COSV100051639, COSV58603342, COSV58603558; called by muse, mutect2, varscan2
- OR4K17 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100210735; called by muse, mutect2, varscan2
- OR4Q3 | c.692T>C p.L231P | Missense Mutation (SNP) | VAF 62/281 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59177765; called by muse, mutect2, varscan2
- OR5AU1 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.95); PolyPhen benign (0.241); catalogued as COSV58616334; called by muse, mutect2, varscan2
- OR6C68 | c.303dup p.A102Cfs*8 | Frame Shift Ins (INS) | VAF 21/63 reads (33%) | catalogued as rs1214120731; called by mutect2, pindel, varscan2
- OR6P1 | c.96del p.F32Lfs*6 | Frame Shift Del (DEL) | VAF 55/184 reads (30%) | catalogued as rs201077183; called by mutect2, varscan2
- P2RY8 | c.370G>T p.G124W | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101184020; called by muse, mutect2, varscan2
- PARD3B | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748008390; called by muse, mutect2, varscan2
- PCDH18 | c.2756C>T p.T919M | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs139751813, COSV61271520; called by muse, mutect2, varscan2
- PCDHB16 | c.2029G>C p.A677P | Missense Mutation (SNP) | VAF 257/582 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV53364645; called by muse, varscan2
- PCDHB3 | c.846del p.H283Mfs*12 | Frame Shift Del (DEL) | VAF 28/75 reads (37%) | catalogued as rs781965023; called by mutect2, pindel, varscan2
- PCDHGA2 | c.2008G>A p.D670N | Missense Mutation (SNP) | VAF 151/372 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as rs755988520, COSV53985455; called by muse, mutect2, varscan2
- PCGF2 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as rs991646402; called by muse, mutect2, varscan2
- PCNX3 | c.1606A>G p.S536G | Missense Mutation (SNP) | VAF 130/317 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs935167914; called by muse, mutect2, varscan2
- PDCD11 | c.1144del p.A382Pfs*5 | Frame Shift Del (DEL) | VAF 87/226 reads (38%) | catalogued as COSV63934252; called by mutect2, pindel, varscan2
- PDK2 | c.27G>C p.K9N | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV50303278; called by muse, mutect2, varscan2
- PER2 | c.871A>G p.M291V | Missense Mutation (SNP) | VAF 172/374 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs777751360; called by muse, mutect2, varscan2
- PES1 | c.188C>T p.T63M | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747963784; called by muse, mutect2, varscan2
- PHEX | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 57/174 reads (33%) | catalogued as COSV65074828; called by muse, mutect2, varscan2
- PI15 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142164571, COSV52642166; called by muse, mutect2, varscan2
- PIDD1 | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs145373644, COSV100204135; called by muse, mutect2, varscan2
- PIK3R2 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as rs770051333; called by muse, mutect2, varscan2
- PITPNM1 | c.451G>T p.G151C | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV56873330; called by muse, mutect2
- PITPNM2 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760673439; called by muse, mutect2, varscan2
- PKN1 | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs972532809; called by muse, mutect2, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 54/138 reads (39%) | catalogued as rs745860467; called by mutect2, varscan2
- PLEC | c.11839G>A p.V3947M (on ENST00000322810 / NM_201380.4; = p.V3837M on NM_000445.5) | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs781838084, COSV59638641; called by muse, mutect2, varscan2
- PLPP5 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 96/215 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs751401210; called by muse, mutect2, varscan2
- PLXNA1 | c.4869C>T p.Y1623= | Splice Region (SNP) | VAF 85/182 reads (47%) | catalogued as rs774909770, COSV52533071; called by muse, mutect2, varscan2
- PLXNC1 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.033); catalogued as rs576172182; called by muse, mutect2, varscan2
- PLXNC1 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.097); catalogued as rs753220527, COSV51570741; called by muse, mutect2, varscan2
- PMF1-BGLAP | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as rs757750903; called by muse, mutect2, varscan2
- PNPLA6 | c.1850G>A p.R617H (on ENST00000414982 / NM_001166111.2; = p.R569H on NM_006702.5) | Missense Mutation (SNP) | VAF 121/269 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV55376354; called by muse, mutect2, varscan2
- POLD3 | c.861del p.A288Qfs*17 | Frame Shift Del (DEL) | VAF 34/107 reads (32%) | catalogued as rs1565122953; called by mutect2, pindel, varscan2
- POTEI | c.2645G>A p.G882E | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1267232336; called by mutect2, varscan2
- PRG4 | c.3497G>A p.R1166Q | Missense Mutation (SNP) | VAF 92/336 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760696470, COSV63355685; called by muse, mutect2, varscan2
- PRPF40B | c.2537C>T p.T846M (on ENST00000380281; = p.T833M on NM_012272.3) | Missense Mutation (SNP) | VAF 87/203 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs770497698; called by muse, mutect2, varscan2
- PRPSAP2 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs371840452; called by muse, mutect2
- PRR12 | c.37del p.H13Tfs*66 (on ENST00000615927; = p.P408Hfs*62 on NM_020719.3) | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as rs763575972; called by mutect2, varscan2
- PSD | c.750del p.S251Afs*43 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | catalogued as rs761494960; called by mutect2, pindel, varscan2
- PTPN13 | c.4643T>C p.I1548T (on ENST00000411767 / NM_080683.3; = p.I1529T on NM_006264.3) | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755854008; called by muse, mutect2, varscan2
- R3HCC1L | c.284A>G p.D95G | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.205); catalogued as rs754242171; called by muse, mutect2, varscan2
- RADIL | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 105/246 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs1250839417, COSV68200163; called by muse, mutect2, varscan2
- RAI1 | c.3446G>A p.R1149H | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs772669262; called by muse, mutect2, varscan2
- RAI2 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.214); catalogued as rs1208705303, COSV58965561; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RANGAP1 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 87/204 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs959441695; called by muse, mutect2, varscan2
- RAPGEF2 | c.3259del p.I1087Ffs*98 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | catalogued as rs760669443; called by mutect2, pindel*, varscan2
- RBBP8 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 92/243 reads (38%) | catalogued as rs771541058; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RNASEH2B | c.925del p.I309Lfs*26 | Frame Shift Del (DEL) | VAF 28/68 reads (41%) | catalogued as rs75254367; ClinVar: benign / likely benign; called by mutect2, varscan2
- RNF113B | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 121/288 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs151316967; called by muse, mutect2, varscan2
- RNF185 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.122); catalogued as rs1436069927, COSV56736567; called by muse, mutect2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 137/220 reads (62%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNMT | c.1180del p.T394Hfs*19 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | catalogued as rs1436309196; called by mutect2, pindel, varscan2
- ROBO2 | c.3233dup p.V1079Sfs*22 | Frame Shift Ins (INS) | VAF 42/104 reads (40%) | catalogued as rs745519558; called by mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 42/128 reads (33%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- SBNO2 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773576513; called by muse, mutect2, varscan2
- SCN5A | c.5139G>T p.W1713C (on ENST00000333535 / NM_198056.3; = p.W1712C on NM_000335.5) | Missense Mutation (SNP) | VAF 134/262 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61134679; called by muse, mutect2, varscan2
- SEC16A | c.3895G>A p.A1299T | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs376172438, COSV51521071; called by muse, mutect2, varscan2
- SEC16B | c.1299del p.S434Vfs*29 | Frame Shift Del (DEL) | VAF 27/79 reads (34%) | catalogued as rs768388757; called by mutect2, pindel, varscan2
- SEC63 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 83/189 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs148837883; called by muse, mutect2, varscan2
- SEH1L | c.5T>C p.F2S | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); catalogued as rs1394599211; called by muse, mutect2, varscan2
- SETD1B | c.2491G>A p.G831R | Missense Mutation (SNP) | VAF 82/216 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1332887731; called by muse, mutect2, varscan2
- SFSWAP | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 87/213 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763274532; called by muse, mutect2, varscan2
- SGK2 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs559824768, COSV58313047; called by muse, mutect2, varscan2
- SGSM1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV68508538; called by muse, mutect2, varscan2
- SH2D4B | c.974C>T p.A325V (on ENST00000646907; = p.A324V on NM_207372.2) | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs761271075; called by muse, mutect2, varscan2
- SH3GL1 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 171/361 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.067); catalogued as rs199700932; called by muse, mutect2, varscan2
- SHCBP1L | c.1017del p.K339Nfs*5 | Frame Shift Del (DEL) | VAF 50/164 reads (30%) | catalogued as rs756742767; called by mutect2, pindel, varscan2
- SHCBP1L | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 89/308 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV62353781; called by muse, mutect2, varscan2
- SLAMF1 | c.829del p.S277Afs*54 | Frame Shift Del (DEL) | VAF 54/232 reads (23%) | catalogued as rs751442558; called by mutect2, varscan2
- SLC17A7 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as rs1424382229; called by muse, mutect2, varscan2
- SLC19A2 | c.1224-4del | Splice Region (DEL) | VAF 40/138 reads (29%) | catalogued as rs750915834; called by mutect2, varscan2
- SLC25A24 | c.1249+2T>C p.X417_splice | Splice Site (SNP) | VAF 12/40 reads (30%) | catalogued as COSV99916197; called by muse, varscan2
- SLC34A2 | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 166/431 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs372824816; called by muse, mutect2, varscan2
- SLC36A1 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 104/262 reads (40%) | catalogued as rs752846011; called by muse, mutect2, varscan2
- SLC6A13 | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.598); catalogued as rs772374178, COSV58259906; called by muse, mutect2, varscan2
- SLC6A3 | c.1762C>T p.R588* | Nonsense Mutation (SNP) | VAF 113/272 reads (42%) | catalogued as rs1333211743, COSV54368060; called by muse, mutect2, varscan2
- SLC7A10 | c.471del p.T158Pfs*12 | Frame Shift Del (DEL) | VAF 40/113 reads (35%) | catalogued as rs753589038, COSV53507811; called by mutect2, pindel, varscan2
- SLC7A13 | c.372del p.S126Afs*20 | Frame Shift Del (DEL) | VAF 47/132 reads (36%) | catalogued as COSV52536834; called by mutect2, pindel, varscan2
- SLC9C2 | c.1577G>C p.R526P | Missense Mutation (SNP) | VAF 69/139 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.216); catalogued as rs775523749, COSV100876690, COSV100876800; called by muse, mutect2, varscan2
- SLITRK1 | c.1502T>C p.L501P | Missense Mutation (SNP) | VAF 69/167 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65676905; called by muse, mutect2, varscan2
- SMYD3 | c.877del p.I293Lfs*4 (on ENST00000490107 / NM_001375962.1; = p.I234Lfs*4 on NM_022743.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 48/228 reads (21%) | catalogued as rs1558435001; called by mutect2, pindel, varscan2
- SNCAIP | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 94/240 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs755797209, COSV99750120; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 38/110 reads (35%) | catalogued as rs768873484; called by mutect2, varscan2
- SOX11 | c.905C>T p.T302I | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs1267359699; called by muse, mutect2, varscan2
- SPDYA | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs771698422, COSV61856457; called by muse, mutect2, varscan2
- SPIRE2 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142759329; called by muse, mutect2, varscan2
- SPTB | c.3649A>G p.M1217V | Missense Mutation (SNP) | VAF 131/356 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as rs146846892; called by muse, mutect2, varscan2
- SRCAP | c.6536del p.K2179Rfs*128 | Frame Shift Del (DEL) | VAF 35/110 reads (32%) | catalogued as COSV52675361; called by mutect2, pindel, varscan2
- SRP19 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); catalogued as rs761772910; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.336G>T p.Q112H | Missense Mutation (SNP) | VAF 57/131 reads (44%) | PolyPhen benign (0.201); catalogued as rs1439404108; called by muse, mutect2, varscan2
- STAP2 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55699249; called by muse, mutect2, varscan2
- SV2B | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 79/227 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1243610540, COSV57702143; called by muse, mutect2, varscan2
- TAF1 | c.5228G>A p.R1743H (on ENST00000373790 / NM_138923.4; = p.R1764H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs758066597; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TANGO6 | c.1171C>T p.R391* | Nonsense Mutation (SNP) | VAF 27/80 reads (34%) | catalogued as rs774043332, COSV55760365; called by muse, mutect2, varscan2
- TARS3 | c.2116G>T p.G706W | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100254486; called by muse, mutect2, varscan2
- TAX1BP1 | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs184528287, COSV55295992; called by muse, mutect2, varscan2
- TBC1D8 | c.2872+5G>A | Splice Region (SNP) | VAF 51/94 reads (54%) | catalogued as rs764939070; called by muse, mutect2, varscan2
- TBX21 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 81/222 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.1); catalogued as rs199527603, COSV51597747; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | catalogued as rs758822980; called by mutect2, varscan2
- TCF20 | c.5826del p.L1943Cfs*118 | Frame Shift Del (DEL) | VAF 26/82 reads (32%) | catalogued as rs756457255; called by mutect2, pindel
- TDRD12 | c.1790del p.N597Ifs*25 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs1052864503; called by mutect2, varscan2
- TENM3 | c.7769C>T p.T2590M | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV101305083; called by muse, mutect2, varscan2
- TEP1 | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52996246; called by muse, mutect2, varscan2
- TLE6 | c.896G>A p.R299Q (on ENST00000246112 / NM_001143986.2; = p.R176Q on NM_024760.3) | Missense Mutation (SNP) | VAF 184/404 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as rs556698104, COSV55736237; called by muse, mutect2, varscan2
- TLN1 | c.6154G>A p.V2052M | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs763070231; called by muse, mutect2, varscan2
- TM4SF5 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749488078; called by muse, mutect2, varscan2
- TMC1 | c.535dup p.S179Kfs*30 | Frame Shift Ins (INS) | VAF 65/229 reads (28%) | catalogued as rs762864983; called by mutect2, pindel, varscan2
- TMEM121B | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 128/265 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1410685856; called by muse, mutect2, varscan2
- TMEM198 | c.467del p.G156Afs*23 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | catalogued as rs1310164939, COSV54719891; called by mutect2, pindel, varscan2
- TMEM240 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 93/286 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); catalogued as rs779413548; called by muse, mutect2, varscan2
- TMEM40 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 24/75 reads (32%) | catalogued as rs756191439, COSV53146248; called by muse, mutect2, varscan2
- TMEM94 | c.657del p.F220Sfs*31 | Frame Shift Del (DEL) | VAF 44/128 reads (34%) | catalogued as rs753764149; called by mutect2, pindel, varscan2
- TMEM94 | c.3433dup p.H1145Pfs*2 | Frame Shift Ins (INS) | VAF 33/84 reads (39%) | catalogued as rs752158523; called by mutect2, varscan2
- TNFRSF1A | c.296G>A p.C99Y | Missense Mutation (SNP) | VAF 113/261 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104895231, CM014114; ClinVar: not provided; called by muse, mutect2, varscan2
- TNFRSF9 | c.345del p.G116Vfs*33 | Frame Shift Del (DEL) | VAF 22/51 reads (43%) | catalogued as rs752649731; called by mutect2, pindel, varscan2
- TNK2 | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.255); catalogued as rs1200360613; called by muse, mutect2, varscan2
- TP53I13 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56402770; called by muse, mutect2, varscan2
- TPPP2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs757325397; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1576C>T p.R526* | Nonsense Mutation (SNP) | VAF 79/254 reads (31%) | catalogued as rs1470581004, COSV50551177; called by muse, mutect2, varscan2
- TTK | c.2571del p.K857Nfs*36 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | catalogued as rs768996038, COSV57882295; called by pindel, varscan2
- TTN | c.90536G>A p.G30179D (on ENST00000591111; = p.G22755D on NM_003319.4) | Missense Mutation (SNP) | VAF 36/66 reads (55%) | PolyPhen possibly damaging (0.755); catalogued as rs1340172871; called by muse, mutect2, varscan2
- TUBGCP6 | c.3996del p.S1333Afs*37 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as COSV50537868; called by mutect2, pindel
- TULP2 | c.967C>T p.R323* | Nonsense Mutation (SNP) | VAF 38/95 reads (40%) | catalogued as rs751465319, COSV55477468; called by muse, mutect2, varscan2
- UBR2 | c.4277C>T p.A1426V | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs762016028; called by muse, mutect2, varscan2
- UBR4 | c.13504C>T p.R4502C | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64391827; called by muse, mutect2, varscan2
- UGT2B17 | c.270del p.F90Lfs*2 | Frame Shift Del (DEL) | VAF 30/77 reads (39%) | catalogued as rs529223604, COSV58502874; called by mutect2, pindel, varscan2
- ULK2 | c.2651A>G p.Q884R | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as rs1192033421; called by muse, mutect2, varscan2
- USF1 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV57035531, COSV57035966; called by muse, mutect2, varscan2
- USP17L1 | c.1357G>A p.G453R | Missense Mutation (SNP) | VAF 169/378 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376292490; called by muse, varscan2
- USP20 | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 78/200 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.618); catalogued as rs142714756; called by muse, mutect2, varscan2
- VASP | c.721-1G>A p.X241_splice | Splice Site (SNP) | VAF 35/102 reads (34%) | catalogued as COSV55607010, COSV55607761; called by muse, mutect2, varscan2
- VEGFB | c.386del p.K129Rfs*5 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | catalogued as rs747177567, COSV100374813; called by mutect2, varscan2
- VPS52 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750380612, COSV71403482; called by muse, mutect2, varscan2
- VWA1 | c.462del p.M155Cfs*51 | Frame Shift Del (DEL) | VAF 66/182 reads (36%) | catalogued as rs760281341; called by mutect2, varscan2
- WDR90 | c.844G>A p.G282S | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs529876871; called by muse, mutect2, varscan2
- WNK4 | c.2183C>T p.S728L | Missense Mutation (SNP) | VAF 80/228 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.339); catalogued as rs1387533241, COSV55906589; called by muse, mutect2, varscan2
- WNT16 | c.500del p.G167Afs*17 (on ENST00000222462 / NM_057168.2; = p.G157Afs*17 on NM_016087.2) | Frame Shift Del (DEL) | VAF 114/316 reads (36%) | catalogued as rs771899177; called by mutect2, varscan2
- WWOX | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 87/196 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs767286260, COSV68349466, COSV68350177; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XCR1 | c.40del p.Y14Tfs*33 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | catalogued as rs1158688440; called by mutect2, pindel
- ZBTB22 | c.1504C>T p.R502W | Missense Mutation (SNP) | VAF 85/173 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV56472452; called by muse, mutect2, varscan2
- ZFHX4 | c.9604del p.I3202Sfs*6 | Frame Shift Del (DEL) | VAF 27/80 reads (34%) | catalogued as rs1563570378; called by mutect2, pindel, varscan2
- ZIM2 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 70/193 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV55625593; called by muse, mutect2, varscan2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as rs753611080; called by mutect2, varscan2
- ZNF219 | c.2157dup p.Q720Afs*13 | Frame Shift Ins (INS) | VAF 13/34 reads (38%) | catalogued as rs771569784; called by mutect2, varscan2
- ZNF251 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376020478; called by muse, mutect2, varscan2
- ZNF311 | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 93/249 reads (37%) | catalogued as rs749224253; called by muse, mutect2, varscan2
- ZNF354C | c.1514A>G p.Y505C | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1218784626; called by muse, mutect2, varscan2
- ZNF574 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as rs575188445; called by muse, mutect2, varscan2
- ZNF691 | c.479G>A p.R160Q (on ENST00000372502; = p.R129Q on NM_015911.3) | Missense Mutation (SNP) | VAF 122/302 reads (40%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.912); catalogued as rs764555560; called by muse, mutect2, varscan2
- ZNF70 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs776168007; called by muse, mutect2, varscan2
- ZNF865 | c.3092G>A p.G1031D | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.09); catalogued as rs1003939062; called by muse, mutect2, varscan2
- ZXDB | c.389del p.G130Afs*13 | Frame Shift Del (DEL) | VAF 29/101 reads (29%) | catalogued as rs1244764887; called by mutect2, pindel, varscan2
- ABCA6 | c.3246del p.I1082Mfs*19 | Frame Shift Del (DEL) | VAF 24/77 reads (31%) | called by mutect2, pindel
- ABCA8 | c.69del p.K23Nfs*4 | Frame Shift Del (DEL) | VAF 17/69 reads (25%) | called by mutect2, pindel, varscan2
- ABHD17A | c.659T>C p.V220A (on ENST00000292577 / NM_001130111.2; = p.V271A on NM_031213.4) | Missense Mutation (SNP) | VAF 114/316 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, varscan2
- ABL1 | c.752dup p.Q252Pfs*46 | Frame Shift Ins (INS) | VAF 42/127 reads (33%) | called by mutect2, pindel, varscan2
- AC004922.1 | c.1226A>G p.Y409C | Missense Mutation (SNP) | VAF 13/259 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ACACB | c.234_235insA p.H79Tfs*30 | Frame Shift Ins (INS) | VAF 49/123 reads (40%) | called by mutect2, pindel, varscan2
- ACAP2 | c.368C>A p.A123D | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- ACSL1 | c.940_942del p.D314del | In Frame Del (DEL) | VAF 32/98 reads (33%) | called by pindel, varscan2
- ACSL4 | c.1821-3del | Splice Region (DEL) | VAF 36/124 reads (29%) | called by mutect2, pindel, varscan2
- ACSM3 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- ADCY1 | c.2639T>A p.F880Y | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ADGRV1 | c.13607del p.L4536Yfs*17 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | called by mutect2, pindel
- ADSS2 | c.1048C>T p.H350Y | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- AGO2 | c.702_705del p.C235Kfs*15 | Frame Shift Del (DEL) | VAF 22/94 reads (23%) | called by pindel, varscan2
- AIP | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 156/394 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- ALG6 | c.315T>A p.S105R | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- AMBP | c.1048T>C p.F350L | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMY2B | c.417G>T p.R139S | Missense Mutation (SNP) | VAF 98/243 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- ANKH | c.317A>G p.Y106C | Missense Mutation (SNP) | VAF 102/238 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKMY2 | c.335_336del p.V112Gfs*15 | Frame Shift Del (DEL) | VAF 25/117 reads (21%) | called by pindel, varscan2
- ANKRD12 | c.6132G>T p.Q2044H | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ANKRD13B | c.1005del p.T336Lfs*26 | Frame Shift Del (DEL) | VAF 35/77 reads (45%) | called by mutect2, pindel, varscan2
- ANKRD24 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD28 | c.1799A>G p.D600G | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ANKRD35 | c.94dup p.D32Gfs*20 | Frame Shift Ins (INS) | VAF 28/115 reads (24%) | called by mutect2, pindel, varscan2
- AP002512.3 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (1); called by muse, mutect2, varscan2
- APBB2 | c.1097_1104+22del p.X366_splice (on ENST00000295974 / NM_001166050.2; = p.X367_splice on NM_004307.2) | Splice Site (DEL) | VAF 29/93 reads (31%) | called by mutect2, pindel
- APH1A | c.359-3del | Splice Region (DEL) | VAF 27/107 reads (25%) | called by mutect2, pindel, varscan2
- APOBR | c.2255C>T p.A752V (on ENST00000431282; = p.A761V on NM_018690.4) | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- ARHGAP24 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 86/194 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- ARHGAP32 | c.2983G>A p.V995I (on ENST00000310343 / NM_001378025.1; = p.V646I on NM_014715.4) | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP4 | c.1778del p.F593Sfs*25 | Frame Shift Del (DEL) | VAF 29/82 reads (35%) | called by mutect2, pindel, varscan2
- ARHGAP42 | c.2540A>G p.Y847C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGEF17 | c.1850del p.P617Lfs*10 | Frame Shift Del (DEL) | VAF 98/287 reads (34%) | called by mutect2, pindel, varscan2
- ARID1A | c.4244del p.Q1415Rfs*66 | Frame Shift Del (DEL) | VAF 27/69 reads (39%) | called by mutect2, pindel*, varscan2
- ARID4B | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ARID5B | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 123/332 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASS1 | c.916G>C p.V306L | Missense Mutation (SNP) | VAF 206/462 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ASTE1 | c.487T>C p.F163L | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATM | c.1081A>G p.T361A | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ATP6V0A2 | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 134/363 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- AXDND1 | c.1535T>C p.V512A | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, varscan2
- AXIN1 | c.2053C>T p.P685S | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- B3GALNT1 | c.982A>G p.T328A | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BAHCC1 | c.1153del p.R385Gfs*3 | Frame Shift Del (DEL) | VAF 33/87 reads (38%) | called by mutect2, pindel, varscan2
- BECN1 | c.1068dup p.L357Vfs*10 | Frame Shift Ins (INS) | VAF 25/89 reads (28%) | called by mutect2, pindel, varscan2
- BICRA | c.2486del p.P829Qfs*13 | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | called by mutect2, pindel, varscan2
- BIRC6 | c.13397C>G p.A4466G | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BMS1 | c.3590C>T p.A1197V | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BPTF | c.5682-1G>A p.X1894_splice | Splice Site (SNP) | VAF 33/88 reads (38%) | called by muse, mutect2
- BRAT1 | c.1553A>G p.D518G | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BSN | c.10895A>G p.D3632G | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- BSN | c.11763del p.K3921Nfs*14 | Frame Shift Del (DEL) | VAF 48/125 reads (38%) | called by mutect2, pindel, varscan2
- BTBD7 | c.864del p.R289Efs*19 | Frame Shift Del (DEL) | VAF 39/125 reads (31%) | called by mutect2, pindel, varscan2
- CACNA1E | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- CAMK2N1 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 57/160 reads (36%) | called by muse, mutect2, varscan2
- CAMSAP3 | c.297del p.N100Tfs*28 | Frame Shift Del (DEL) | VAF 33/102 reads (32%) | called by mutect2, pindel, varscan2
- CAMSAP3 | c.1874T>C p.F625S | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CANX | c.1305dup p.D436* | Frame Shift Ins (INS) | VAF 62/184 reads (34%) | called by mutect2, varscan2
- CASP4 | c.1130A>T p.N377I | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CATSPER1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- CBLIF | c.833A>C p.K278T | Missense Mutation (SNP) | VAF 87/211 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CC2D1A | c.2759C>T p.A920V | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- CCND1 | c.844_870del p.D282_V290del | In Frame Del (DEL) | VAF 31/75 reads (41%) | called by mutect2, pindel
- CD8A | c.528del p.L177Wfs*115 | Frame Shift Del (DEL) | VAF 146/400 reads (37%) | called by mutect2, pindel, varscan2
- CDC20 | c.1127del p.G376Afs*18 | Frame Shift Del (DEL) | VAF 52/132 reads (39%) | called by mutect2, pindel, varscan2
- CDH11 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CDHR1 | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 93/216 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CDK5RAP2 | c.3548T>C p.V1183A | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- CENPK | c.232del p.T78Hfs*7 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | called by mutect2, pindel, varscan2
- CEP162 | c.4016A>G p.Q1339R | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- CEP290 | c.5972dup p.R1992Efs*4 | Frame Shift Ins (INS) | VAF 26/87 reads (30%) | called by mutect2, pindel, varscan2
- CFAP54 | c.9271A>T p.I3091L | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- CHD9 | c.2280del p.F760Lfs*16 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel
- CHMP7 | c.818G>A p.C273Y | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- CLEC14A | c.1363A>G p.S455G | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLEC16A | c.1148G>A p.G383D | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- COG1 | c.2112T>G p.D704E | Missense Mutation (SNP) | VAF 123/287 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL19A1 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL4A2 | c.4264del p.Q1422Rfs*37 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- COL4A3 | c.3408_3409del p.G1137Pfs*19 | Frame Shift Del (DEL) | VAF 92/326 reads (28%) | called by pindel, varscan2
- COL4A5 | c.1247T>A p.I416N | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- COL5A1 | c.3821G>A p.G1274E | Missense Mutation (SNP) | VAF 128/294 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, varscan2
- COL8A1 | c.1795del p.H599Mfs*24 | Frame Shift Del (DEL) | VAF 60/161 reads (37%) | called by mutect2, varscan2
- COMMD9 | c.368T>G p.L123R | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CORIN | c.148G>C p.V50L | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CPN2 | c.370G>T p.G124C | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- CREBRF | c.1538C>T p.T513I | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CRY1 | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, varscan2
- CTCF | c.610del p.T204Qfs*18 | Frame Shift Del (DEL) | VAF 115/390 reads (29%) | called by mutect2, pindel, varscan2
- CUX2 | c.2603A>G p.Y868C | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CYP26B1 | c.11A>G p.E4G | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CYP2C19 | c.707del p.N236Tfs*13 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | called by mutect2, pindel, varscan2
- CYP2E1 | c.1133del p.F378Sfs*12 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | called by mutect2, pindel
- CYTH2 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- DCPS | c.476G>T p.R159M | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2
- DDX19B | c.917C>G p.T306S | Missense Mutation (SNP) | VAF 130/284 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDX42 | c.647dup p.N216Kfs*5 | Frame Shift Ins (INS) | VAF 22/66 reads (33%) | called by mutect2, varscan2
- DDX49 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- DGAT2 | c.1149G>T p.E383D | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.81); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DGLUCY | c.660G>T p.E220D | Missense Mutation (SNP) | VAF 74/184 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIDO1 | c.4726del p.E1576Sfs*288 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | called by mutect2, varscan2
- DIDO1 | c.2735C>G p.S912C | Missense Mutation (SNP) | VAF 89/192 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DIMT1 | c.507T>A p.D169E | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DIP2A | c.4247C>T p.A1416V | Missense Mutation (SNP) | VAF 80/225 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- DLC1 | c.2487del p.S830Rfs*7 (on ENST00000276297 / NM_001348081.2; = p.S393Rfs*7 on NM_006094.5) | Frame Shift Del (DEL) | VAF 52/148 reads (35%) | called by mutect2, pindel, varscan2
- DMD | c.10027dup p.S3343Ffs*9 | Frame Shift Ins (INS) | VAF 94/264 reads (36%) | called by mutect2, varscan2
- DNAH5 | c.6536C>T p.T2179M | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DNM3 | c.353_354del p.I118Tfs*3 | Frame Shift Del (DEL) | VAF 18/81 reads (22%) | called by mutect2, pindel, varscan2
- DOK5 | c.803A>G p.Y268C | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DOP1A | c.5062A>G p.R1688G | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- DUOXA1 | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 138/365 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DUSP22 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- DYNC2I1 | c.1838G>A p.S613N | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIF5A | c.381C>A p.Y127* | Nonsense Mutation (SNP) | VAF 65/135 reads (48%) | called by muse, mutect2, varscan2
- EMX2 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 106/286 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- ENGASE | c.322C>A p.L108M | Missense Mutation (SNP) | VAF 110/280 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- EPB41L5 | c.1880T>C p.V627A | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERMP1 | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EXOSC5 | c.626G>A p.C209Y | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAM120B | c.1811G>T p.S604I | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM184B | c.980T>A p.V327D | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- FAM186A | c.2113del p.R705Efs*7 | Frame Shift Del (DEL) | VAF 31/78 reads (40%) | called by mutect2, pindel, varscan2
- FBXL18 | c.317G>T p.W106L | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXO38 | c.2090dup p.N697Kfs*44 | Frame Shift Ins (INS) | VAF 48/138 reads (35%) | called by mutect2, varscan2
- FECH | c.943A>G p.T315A | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FER1L5 | c.3575del p.G1192Dfs*21 (on ENST00000623019; = p.G1165Dfs*21 on NM_001293083.2) | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | called by mutect2, pindel, varscan2
- FGF13 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.511); called by muse, mutect2
- FIGN | c.27_29delinsT p.T10Mfs*14 | Frame Shift Del (DEL) | VAF 33/110 reads (30%) | called by pindel, varscan2*
- FIGNL2 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 104/204 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- FLI1 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- FLT4 | c.1267del p.Q423Rfs*70 | Frame Shift Del (DEL) | VAF 87/232 reads (38%) | called by mutect2, varscan2
- FOCAD | c.1531T>C p.Y511H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FOXC1 | c.1075T>G p.S359A | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- FOXP1 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- FSCB | c.1834C>A p.P612T | Missense Mutation (SNP) | VAF 80/234 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.142); called by muse, varscan2
- FUT8 | c.1207del p.R403Efs*12 (on ENST00000360689 / NM_001371534.1; = p.R240Efs*12 on NM_004480.4) | Frame Shift Del (DEL) | VAF 27/75 reads (36%) | called by mutect2, pindel, varscan2
- FYCO1 | c.3190A>G p.S1064G | Missense Mutation (SNP) | VAF 178/451 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GAPVD1 | c.2139A>C p.E713D | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- GAREM2 | c.1124C>A p.P375Q | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- GASK1A | c.490_491del p.Q164Efs*2 | Frame Shift Del (DEL) | VAF 35/95 reads (37%) | called by pindel, varscan2
- GATM | c.1104del p.K368Nfs*60 | Frame Shift Del (DEL) | VAF 46/115 reads (40%) | called by mutect2, pindel, varscan2
- GBF1 | c.3256C>G p.L1086V (on ENST00000369983 / NM_001377137.1; = p.L1085V on NM_004193.3) | Missense Mutation (SNP) | VAF 100/265 reads (38%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- GDF1 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.1); called by muse, mutect2, varscan2
- GFPT2 | c.1672C>A p.L558M | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GIGYF1 | c.809del p.G270Efs*75 | Frame Shift Del (DEL) | VAF 45/131 reads (34%) | called by mutect2, pindel, varscan2
- GLRX2 | c.472del p.S158Vfs*22 (on ENST00000367439 / NM_197962.3; = p.S159Vfs*22 on NM_016066.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | called by mutect2, varscan2
- GNAT3 | c.813del p.D272Ifs*7 | Frame Shift Del (DEL) | VAF 26/82 reads (32%) | called by mutect2, varscan2
- GOLGA4 | c.5004del p.G1669Vfs*6 | Frame Shift Del (DEL) | VAF 28/85 reads (33%) | called by mutect2, pindel, varscan2
- GREM2 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); called by muse, mutect2
- GRIK4 | c.1078A>G p.T360A | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GRIN2A | c.4326del p.R1443Gfs*3 | Frame Shift Del (DEL) | VAF 55/141 reads (39%) | called by mutect2, pindel, varscan2
- GRK1 | c.1246C>A p.P416T | Missense Mutation (SNP) | VAF 71/188 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRM5 | c.2636A>G p.K879R | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- HBM | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 184/437 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- HEATR6 | c.1837A>G p.N613D | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HELZ2 | c.6638del p.G2213Vfs*22 (on ENST00000467148 / NM_001037335.2; = p.G1644Vfs*22 on NM_033405.3) | Frame Shift Del (DEL) | VAF 21/53 reads (40%) | called by mutect2, pindel, varscan2
- HIP1R | c.358-1G>T p.X120_splice | Splice Site (SNP) | VAF 46/89 reads (52%) | called by muse, mutect2
- HIRIP3 | c.388_390del p.E130del | In Frame Del (DEL) | VAF 43/143 reads (30%) | called by pindel, varscan2
- HIVEP2 | c.1823T>A p.V608D | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HMGB3 | c.533A>G p.K178R | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- HMGN5 | c.825del p.E276Rfs*18 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, pindel, varscan2
- HMGXB4 | c.689A>G p.D230G | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- HMX3 | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); called by muse, varscan2
- HOXA5 | c.761A>T p.N254I | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HOXC12 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 16/273 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.057); called by muse, mutect2
- HSP90AA1 | c.1973C>A p.S658Y | Missense Mutation (SNP) | VAF 86/217 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HSPA12A | c.1028G>A p.G343D | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ICMT | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- IFITM5 | c.39del p.T14Rfs*24 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel
- IL7R | c.361del p.I121* | Frame Shift Del (DEL) | VAF 34/92 reads (37%) | called by mutect2, varscan2
- IL9R | c.1408C>A p.L470M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.739); called by mutect2, varscan2
- INPP5D | c.3523C>T p.P1175S (on ENST00000445964 / NM_001017915.3; = p.P1174S on NM_005541.5) | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); called by muse, mutect2
- INPP5F | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- INSR | c.25del p.A9Rfs*56 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | called by mutect2, pindel, varscan2
- INTS6L | c.1996C>A p.L666I | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2
- ISCU | c.196del p.A66Lfs*7 (on ENST00000311893 / NM_213595.4; = p.A41Lfs*7 on NM_014301.4) | Frame Shift Del (DEL) | VAF 95/272 reads (35%) | called by mutect2, pindel, varscan2
- ISM1 | c.238C>G p.P80A | Missense Mutation (SNP) | VAF 100/265 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ITPKB | c.1579C>T p.Q527* | Nonsense Mutation (SNP) | VAF 41/107 reads (38%) | called by muse, mutect2, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 109/141 reads (77%) | called by mutect2, varscan2
- KAT2B | c.2338A>G p.R780G | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, varscan2
- KBTBD3 | c.922A>G p.N308D | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCND3 | c.1613G>A p.S538N | Missense Mutation (SNP) | VAF 197/465 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- KCNH2 | c.2855C>A p.P952H | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- KCNH5 | c.1543A>G p.M515V | Missense Mutation (SNP) | VAF 77/174 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- KCNH7 | c.3447T>A p.D1149E | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KDM8 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- KERA | c.459G>T p.K153N | Missense Mutation (SNP) | VAF 74/191 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- KIAA1614 | c.1198_1202del p.G400Pfs*52 | Frame Shift Del (DEL) | VAF 38/171 reads (22%) | called by mutect2, pindel, varscan2
- KIF3C | c.845C>G p.A282G | Missense Mutation (SNP) | VAF 88/173 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF4A | c.3268G>T p.G1090C | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- KLHL23 | c.306_308del p.T103del | In Frame Del (DEL) | VAF 17/70 reads (24%) | called by mutect2, pindel, varscan2
- KLHL31 | c.1559G>A p.G520D | Missense Mutation (SNP) | VAF 91/198 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2A | c.1660del p.Q554Sfs*13 | Frame Shift Del (DEL) | VAF 74/206 reads (36%) | called by mutect2, pindel, varscan2
- KMT2B | c.649del p.R217Gfs*22 | Frame Shift Del (DEL) | VAF 23/86 reads (27%) | called by mutect2, pindel, varscan2
- KMT2B | c.3302del p.P1101Lfs*81 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | called by mutect2, pindel, varscan2
- KMT2D | c.7061del p.P2354Lfs*30 | Frame Shift Del (DEL) | VAF 48/129 reads (37%) | called by mutect2, pindel, varscan2
- KMT2D | c.1966dup p.L656Pfs*12 | Frame Shift Ins (INS) | VAF 8/21 reads (38%) | called by mutect2, pindel, varscan2
- KMT5B | c.1166del p.N389Tfs*13 (on ENST00000304363 / NM_001300907.1; = p.N389Tfs*24 on NM_016028.4) | Frame Shift Del (DEL) | VAF 37/92 reads (40%) | called by mutect2, pindel, varscan2
- KRT24 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- LAMA5 | c.10495A>G p.R3499G | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LATS2 | c.1889A>T p.E630V | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- LIMS1 | c.604G>T p.G202W | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LOXHD1 | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 74/167 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRFN4 | c.246T>A p.N82K | Missense Mutation (SNP) | VAF 82/196 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1 | c.13258+1G>A p.X4420_splice | Splice Site (SNP) | VAF 60/131 reads (46%) | called by muse, mutect2, varscan2
- LRP2 | c.7780C>T p.H2594Y | Missense Mutation (SNP) | VAF 104/208 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC1 | c.1414A>G p.T472A | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- LYSMD1 | c.36del p.S13Qfs*23 | Frame Shift Del (DEL) | VAF 44/173 reads (25%) | called by mutect2, pindel, varscan2
- MAGEB1 | c.545A>T p.N182I | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, varscan2
- MAGEB1 | c.606G>T p.M202I | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); called by muse, varscan2
- MAGEB6B | c.814A>G p.N272D | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAIP1 | c.820G>T p.G274* | Nonsense Mutation (SNP) | VAF 39/102 reads (38%) | called by muse, mutect2, varscan2
- MAP3K5 | c.4115_4118del p.K1372Rfs*8 | Frame Shift Del (DEL) | VAF 52/151 reads (34%) | called by pindel, varscan2
- MAP3K9 | c.2022G>T p.E674D | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- MAP4 | c.3145C>T p.P1049S | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAPK6 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- MAS1L | c.1076A>G p.H359R | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- MCF2L | c.1885G>A p.A629T (on ENST00000375608; = p.A597T on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MCM2 | c.1246G>T p.G416C | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- MEIS3 | c.284dup p.G96Wfs*3 | Frame Shift Ins (INS) | VAF 59/153 reads (39%) | called by mutect2, pindel, varscan2
- MIA2 | c.176dup p.L59Ffs*6 | Frame Shift Ins (INS) | VAF 44/104 reads (42%) | called by mutect2, varscan2
- MID2 | c.1741G>C p.A581P | Missense Mutation (SNP) | VAF 61/171 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- MKNK2 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- MOB4 | c.318G>A p.W106* | Nonsense Mutation (SNP) | VAF 23/76 reads (30%) | called by muse, mutect2, varscan2
- MOV10L1 | c.1387A>G p.K463E | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MREG | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MROH9 | c.1426C>T p.Q476* | Nonsense Mutation (SNP) | VAF 29/118 reads (25%) | called by muse, mutect2, varscan2
- MRPS25 | c.386T>C p.F129S | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MS4A10 | c.133C>T p.H45Y | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- MS4A6A | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- MTA1 | c.1805C>A p.P602H | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MTNR1A | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- MTOR | c.7180G>A p.G2394S | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTSS1 | c.880T>C p.S294P | Missense Mutation (SNP) | VAF 128/322 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MUC16 | c.33676A>G p.T11226A | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- MUC16 | c.26367dup p.K8790Qfs*48 | Frame Shift Ins (INS) | VAF 45/128 reads (35%) | called by mutect2, pindel, varscan2
- MUC5B | c.2107T>C p.Y703H | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- MYH7B | c.510G>A p.W170* | Nonsense Mutation (SNP) | VAF 52/131 reads (40%) | called by muse, mutect2, varscan2
- MYH8 | c.2354C>T p.A785V | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYH9 | c.2287_2289del p.F763del | In Frame Del (DEL) | VAF 92/268 reads (34%) | called by pindel, varscan2
- MYO10 | c.4612C>A p.H1538N | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- MYO1F | c.2228A>G p.Y743C | Missense Mutation (SNP) | VAF 175/412 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- N4BP3 | c.852+1G>C p.X284_splice | Splice Site (SNP) | VAF 24/44 reads (55%) | called by muse, varscan2
- NEB | c.9565A>T p.T3189S | Missense Mutation (SNP) | VAF 86/169 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- NEB | c.732del p.G245Vfs*18 | Frame Shift Del (DEL) | VAF 85/234 reads (36%) | called by mutect2, pindel, varscan2
- NEMP1 | c.607A>G p.I203V (on ENST00000300128 / NM_001130963.2; = p.I130V on NM_015257.3) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NKAIN4 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- NKX1-1 | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- NLRX1 | c.2393T>C p.V798A | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NMT1 | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- NOS2 | c.66del p.D23Tfs*17 | Frame Shift Del (DEL) | VAF 63/187 reads (34%) | called by mutect2, pindel, varscan2
- NSD1 | c.4591del p.M1531Cfs*43 | Frame Shift Del (DEL) | VAF 129/359 reads (36%) | called by mutect2, pindel, varscan2
- NUTF2 | c.266T>C p.L89P | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); called by muse, mutect2
- NYAP2 | c.945del p.K316Rfs*57 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | called by mutect2, pindel, varscan2
- OBI1 | c.776del p.N259Ifs*9 | Frame Shift Del (DEL) | VAF 24/86 reads (28%) | called by mutect2, pindel, varscan2
- OBSCN | c.16445T>C p.L5482P | Missense Mutation (SNP) | VAF 63/269 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OCRL | c.1709G>T p.R570M | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); called by muse, mutect2
- OGT | c.629C>A p.A210E | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OLFM3 | c.1376G>A p.G459D (on ENST00000338858 / NM_001288821.1; = p.G439D on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ONECUT2 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR10V1 | c.401G>T p.R134M | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- OR12D3 | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2J2 | c.777G>A p.M259I | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4F6 | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR4N2 | c.469A>G p.I157V | Missense Mutation (SNP) | VAF 82/287 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- OR5V1 | c.548dup p.L184Ffs*13 | Frame Shift Ins (INS) | VAF 26/83 reads (31%) | called by mutect2, pindel, varscan2
- OXNAD1 | c.653dup p.N218Kfs*8 | Frame Shift Ins (INS) | VAF 26/84 reads (31%) | called by mutect2, pindel
- PASK | c.3487del p.C1163Vfs*63 | Frame Shift Del (DEL) | VAF 87/259 reads (34%) | called by mutect2, pindel, varscan2
- PATZ1 | c.1724A>G p.K575R | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PAX2 | c.1207del p.R403Gfs*37 (on ENST00000428433 / NM_003987.5; = p.R380Gfs*37 on NM_000278.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 88/263 reads (33%) | called by mutect2, pindel, varscan2
- PCDH1 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, varscan2
- PCDH15 | c.737C>T p.T246I | Missense Mutation (SNP) | VAF 126/359 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHA2 | c.1006del p.I336Ffs*3 | Frame Shift Del (DEL) | VAF 49/132 reads (37%) | called by mutect2, pindel, varscan2
- PCDHB6 | c.1772A>G p.D591G | Missense Mutation (SNP) | VAF 45/449 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCNX4 | c.2570_2572del p.V857del (on ENST00000406854 / NM_001330177.2; = p.V623del on NM_022495.5) | In Frame Del (DEL) | VAF 38/90 reads (42%) | called by mutect2, pindel, varscan2
- PCOLCE | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDE5A | c.1916C>T p.T639I | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- PDZD8 | c.3346del p.I1116* | Frame Shift Del (DEL) | VAF 51/176 reads (29%) | called by mutect2, pindel, varscan2
- PF4V1 | c.100+2T>C p.X34_splice | Splice Site (SNP) | VAF 49/129 reads (38%) | called by muse, mutect2, varscan2
- PHF20 | c.2191T>G p.Y731D | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PICALM | c.329dup p.L110Ffs*3 | Frame Shift Ins (INS) | VAF 21/49 reads (43%) | called by mutect2, pindel, varscan2
- PIGO | c.1052del p.G351Vfs*11 | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | called by mutect2, pindel, varscan2
- PIM3 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PIP4K2A | c.237del p.F79Lfs*38 | Frame Shift Del (DEL) | VAF 47/128 reads (37%) | called by mutect2, pindel, varscan2
- PKD2L2 | c.1245del p.F415Lfs*2 | Frame Shift Del (DEL) | VAF 36/129 reads (28%) | called by mutect2, pindel, varscan2
- PLA2G6 | c.1177del p.I393Sfs*11 | Frame Shift Del (DEL) | VAF 131/398 reads (33%) | called by mutect2, pindel, varscan2
- PLCL2 | c.3275C>T p.A1092V (on ENST00000615277 / NM_001144382.2; = p.A966V on NM_015184.5) | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- PLIN5 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- PLS3 | c.1611del p.K537Nfs*22 | Frame Shift Del (DEL) | VAF 37/108 reads (34%) | called by mutect2, pindel, varscan2
- POR | c.974T>C p.V325A | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- POU3F1 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPM1E | c.2246C>A p.P749H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRAM1 | c.1264G>T p.G422C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- PRKCSH | c.386A>G p.Q129R | Missense Mutation (SNP) | VAF 168/358 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PROZ | c.691+2T>C p.X231_splice | Splice Site (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- PRPF39 | c.1437G>T p.Q479H | Missense Mutation (SNP) | VAF 88/247 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- PSMB7 | c.215A>G p.K72R | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- PSMG1 | c.580del p.T194Hfs*13 | Frame Shift Del (DEL) | VAF 73/230 reads (32%) | called by mutect2, pindel, varscan2
- PTGDR2 | c.698T>C p.L233S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- PTPN13 | c.4354G>T p.G1452* (on ENST00000411767 / NM_080683.3; = p.G1433* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.790del p.C264Vfs*14 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- PTPRZ1 | c.5804C>T p.A1935V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PURA | c.897_899del p.Q303del | In Frame Del (DEL) | VAF 21/54 reads (39%) | called by mutect2, pindel, varscan2
- RAB3GAP2 | c.1940A>C p.E647A | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- RAPGEF6 | c.3388A>G p.M1130V | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RB1CC1 | c.2736A>C p.E912D | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- RBM6 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- RBMS1 | c.35A>G p.Q12R | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RC3H1 | c.1424C>A p.A475D | Missense Mutation (SNP) | VAF 74/272 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- RGS9 | c.1291T>C p.S431P | Missense Mutation (SNP) | VAF 80/242 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- RNASET2 | c.336G>C p.K112N | Missense Mutation (SNP) | VAF 103/299 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- RNF215 | c.1011G>A p.W337* | Nonsense Mutation (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2, varscan2
- RNPS1 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 84/183 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- RPF1 | c.285+2T>C p.X95_splice | Splice Site (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- RRM1 | c.320C>A p.P107Q | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RUBCN | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 62/123 reads (50%) | SIFT tolerated (0.75); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- RWDD3 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); called by muse, varscan2
- RYR2 | c.3458G>T p.G1153V | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RYR3 | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SAFB | c.2023C>T p.H675Y | Missense Mutation (SNP) | VAF 157/398 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- SBNO2 | c.1810T>C p.F604L | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SCAF8 | c.532T>C p.W178R | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SCAMP5 | c.176T>C p.L59P | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SCAP | c.3647C>T p.T1216I | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SCN10A | c.4841T>C p.L1614P | Missense Mutation (SNP) | VAF 115/240 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SCN2A | c.1517_1527del p.K506Tfs*12 | Frame Shift Del (DEL) | VAF 76/216 reads (35%) | called by mutect2, pindel, varscan2
- SCYL1 | c.1040A>G p.Q347R | Missense Mutation (SNP) | VAF 89/194 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SEC16A | c.6949G>A p.A2317T | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SECISBP2L | c.2458G>A p.D820N (on ENST00000559471 / NM_001193489.2; = p.D775N on NM_014701.4) | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- SEMA6C | c.2361del p.A788Pfs*3 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | called by mutect2, pindel, varscan2
- SENP6 | c.833A>G p.N278S | Missense Mutation (SNP) | VAF 78/163 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SERTAD3 | c.512del p.P171Lfs*61 | Frame Shift Del (DEL) | VAF 52/136 reads (38%) | called by pindel, varscan2
- SETDB1 | c.2864del p.P955Hfs*11 | Frame Shift Del (DEL) | VAF 35/125 reads (28%) | called by mutect2, pindel, varscan2
- SFT2D1 | c.192del p.F64Lfs*13 | Frame Shift Del (DEL) | VAF 48/129 reads (37%) | called by mutect2, pindel, varscan2
- SFXN2 | c.621G>T p.K207N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- SH3BP4 | c.2195G>A p.G732D | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SHISA7 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SIGLEC1 | c.4106T>C p.V1369A | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SIKE1 | c.360del p.A121Rfs*8 | Frame Shift Del (DEL) | VAF 41/95 reads (43%) | called by mutect2, varscan2
- SIM1 | c.145T>C p.Y49H | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIPA1L3 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SLAIN1 | c.291-1G>A p.X97_splice (on ENST00000466548; = p.S119N on NM_001242868.2) | Splice Site (SNP) | VAF 69/163 reads (42%) | called by muse, mutect2, varscan2
- SLC15A5 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SLC16A1 | c.672dup p.D225Rfs*4 | Frame Shift Ins (INS) | VAF 80/233 reads (34%) | called by mutect2, pindel, varscan2
- SLC25A41 | c.379A>G p.T127A | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SLC25A42 | c.392del p.P131Lfs*18 | Frame Shift Del (DEL) | VAF 50/128 reads (39%) | called by mutect2, pindel, varscan2
- SLC35G5 | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC9A3 | c.1031G>A p.S344N | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- SLCO2B1 | c.1466G>A p.C489Y | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLX4 | c.4801T>C p.Y1601H | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SORCS1 | c.2062del p.E688Kfs*94 | Frame Shift Del (DEL) | VAF 25/74 reads (34%) | called by mutect2, pindel, varscan2
- SOX17 | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 114/264 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- SOX30 | c.1699G>T p.E567* | Nonsense Mutation (SNP) | VAF 80/112 reads (71%) | called by muse, mutect2, varscan2
- SPAG5 | c.509T>C p.V170A | Missense Mutation (SNP) | VAF 86/233 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SPATA31A6 | c.1802del p.K601Sfs*19 | Frame Shift Del (DEL) | VAF 72/259 reads (28%) | called by mutect2, pindel, varscan2
- SPATA31A7 | c.1814del p.K605Sfs*19 | Frame Shift Del (DEL) | VAF 40/430 reads (9%) | called by pindel, varscan2
- SPI1 | c.425del p.P142Hfs*44 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel
- SPINK5 | c.808del p.S270Qfs*25 | Frame Shift Del (DEL) | VAF 54/148 reads (36%) | called by mutect2, pindel, varscan2
- SPSB3 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 83/190 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- STOX1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.177); called by muse, mutect2
- SUPT20HL2 | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SUV39H1 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- SVEP1 | c.6408del p.M2137Cfs*17 | Frame Shift Del (DEL) | VAF 45/116 reads (39%) | called by mutect2, pindel, varscan2
- SYMPK | c.2651G>A p.R884Q | Missense Mutation (SNP) | VAF 73/202 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- SYNE1 | c.3290C>T p.T1097I (on ENST00000367255 / NM_182961.4; = p.T1104I on NM_033071.3) | Missense Mutation (SNP) | VAF 126/291 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SYNE2 | c.2031del p.K677Nfs*30 | Frame Shift Del (DEL) | VAF 30/95 reads (32%) | called by mutect2, pindel, varscan2
- SYVN1 | c.1194del p.S399Afs*86 (on ENST00000377190 / NM_172230.3; = p.S399Afs*85 on NM_032431.3) | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
455 further variants in this file (71 protein-altering or splice-affecting, 227 silent, 157 other) are not listed here.
